Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5591, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5591-01A (Primary Tumor).

Surgical Pathology
REVISED REPORT (Addendum/Procedure included)

TISSUE DESCRIPTION:

Right kidney (16 x 15 x 6 cm) with 7 cm of left ureter, biopsy from right kidney (3 x 2 x 0.8 cm), tissue from right lower lobe lung (No.1--5.5 x 2.4 x 1.3 cm and No.2--0.8 x 0.8 x 0.7 cm), retrocaval lymph nodes and intra-aortic caval tissue (2.3 x 1.5 x 0.9 cm)

DIAGNOSIS:

Kidney, right, biopsy: Grade 2 (of 4) renal cell carcinoma, clear cell type. Coagulative necrosis present.

Kidney, right, radical nephrectomy: Grade 2 (of 4) renal cell carcinoma, clear cell type, forms a 14.0 x 10.0 x 6.0 cm mass located in the right kidney. The tumor extends into the perinephric fat. The renal vein is grossly free of tumor. The tumor does not involve the collecting system. Coagulative tumor necrosis is present. Sarcomatoid differentiation is absent. The surgical margins are negative. No renal hilar lymph nodes are identified. The adrenal gland is absent.

Lung, right lower lobe, wedge excision No.1: Metastatic grade 2 (of 4) renal cell carcinoma forming a 1.0 cm nodule. Surgical margins are free of involvement.

Lung, right lower lobe, wedge excision No.2: Metastatic grade 2 (of 4) renal cell carcinoma forming a 0.8 cm nodule.

Lymph nodes, retrocaval, excision: Multiple (2) retrocaval lymph nodes are negative for tumor.

Soft tissue, intra-aortic caval region, excision: Benign fibroadipose and nerve tissue.

ADDENDUM:

Immunohistochemical stain for EGFR shows 100% of tumor cells positive, with 2+ intensity. This tumor can be considered an EGFR-expressing carcinoma. Response to treatment does not appear to correlate with intensity of staining or number of cells positive.

Source: NCI Genomic Data Commons file 62ffa180-1854-4090-8da1-58fc75bb719b (TCGA-CW-5591.C5BEE382-DF45-4A2C-8774-F39F93544810.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).